Gene-level copy-number profile of tumor specimen TARGET-40-PAPVYW-01A from TARGET case TARGET-40-PAPVYW, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 7.7 years (2,803 days).
Specimen TARGET-40-PAPVYW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.e0e08dca-bc2d-519d-a6b9-ca37868561a1.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAPVYW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate.
https://portal.gdc.cancer.gov/files/eabe84e4-5bff-4483-8069-4db758603e2b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 6,238; copy number 3: 2,787; copy number 4: 45,675; copy number 5: 3,319; copy number 6: 1,131; copy number 7: 112; copy number 8: 79; copy number 9: 68; copy number 10: 75; copy number 11: 155; copy number 12: 54; copy number 13: 58; copy number 14: 70; copy number 15: 112; copy number 16: 13; copy number 17: 62; copy number 18: 2; copy number 20: 3; copy number 22: 11; copy number 23: 1; copy number 24: 2; copy number 26: 30; copy number 28: 23; copy number 30: 24; copy number 37: 22; copy number 39: 22; copy number 41: 67; copy number 42: 5; copy number 48: 2; copy number 52: 16; copy number 58: 3; copy number 64: 15.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 915 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,548,562–150,964,744, 23 genes, copy number 9 (within-gene range 6–9): ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1.
- chr8:73,831,143–75,566,834, 36 genes, copy number 42–64 (within-gene range 4–64): AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr8:78,805,293–78,956,082, 1 gene, copy number 48 (within-gene range 4–48): AC083837.1.
- chr8:79,259,402–79,314,951, 1 gene, copy number 48: AC138646.1.
- chr8:81,149,107–82,961,926, 30 genes, copy number 26–39 (within-gene range 4–39): AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1.
- chr8:84,182,787–85,617,512, 22 genes, copy number 26 (within-gene range 3–26): RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1.
- chr8:90,001,405–106,770,244, 317 genes, copy number 9–37 (broad region; genes not listed).
- chr8:111,093,263–113,436,939, 12 genes, copy number 9–12 (within-gene range 2–12): LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:115,408,496–116,325,062, 4 genes, copy number 18–24 (within-gene range 4–24): TRPS1, AF178030.1, LINC00536, RNA5SP276.
- chr8:116,642,130–118,111,826, 16 genes, copy number 12–23: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1.
- chr8:121,639,293–121,994,185, 1 gene, copy number 15 (within-gene range 4–15): HAS2-AS1.
- chr8:121,954,640–140,458,579, 241 genes, copy number 10–58 (within-gene range 4–58) (broad region; genes not listed).
- chr10:76,558,350–86,403,201, 148 genes, copy number 11–15 (broad region; genes not listed).
- chr15:26,395,037–28,884,655, 61 genes, copy number 11–13 (broad region; genes not listed).
- chr15:47,730,144–47,846,266, 2 genes, copy number 12: AC044787.1, LINC01491.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
